Somatic mutation profile of tumor specimen TARGET-40-NAAGJS-01A (aliquot TARGET-40-NAAGJS-01A-01D) from TARGET case TARGET-40-NAAGJS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.5 years (3,833 days).
Specimen TARGET-40-NAAGJS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40a91ada-e509-4b62-b5bf-3df532fb426f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJS-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cb4d4fb-1f31-4103-bc35-910f7cc66bb2

The open-access MAF lists 28 somatic variants for this specimen: 16 protein-altering or splice-affecting, 8 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, RNA 2, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX16 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as rs767625377; called by muse, varscan2
- NLRP11 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV64088132; called by muse, varscan2
- SPTA1 | c.4445G>T p.W1482L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935764; called by muse, varscan2
- ADCY6 | c.1097T>A p.M366K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, varscan2
- BARX1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAP2 | c.1387T>C p.W463R | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GLT1D1 | c.376-2A>T p.X126_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- IL4I1 | c.1093C>A p.R365S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- KRTAP10-8 | c.536T>A p.V179D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- PIK3CG | c.2316A>C p.E772D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.05); called by muse, mutect2
- SMOX | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, varscan2
- SPECC1L | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.149); called by muse, varscan2
- TMEM132C | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by mutect2, varscan2
- TMEM88 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.901); called by muse, varscan2
- TTC13 | c.2021A>G p.N674S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- VWF | c.7496G>T p.C2499F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ATP6AP1 | c.1131G>A p.L377= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- CSMD3 | c.7407A>T p.I2469= (on ENST00000297405 / NM_001363185.1; = p.I2365= on NM_052900.3) | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- GRIN2A | c.276G>A p.G92= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2
- KIAA2012 | c.2448C>T p.S816= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs969618865; called by muse, varscan2
- RBM5 | c.372T>C p.P124= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs146743332; called by muse, varscan2
- SYNE1 | c.6015A>T p.R2005= (on ENST00000367255 / NM_182961.4; = p.R2012= on NM_033071.3) | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TNKS | c.2991C>T p.G997= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, varscan2
- TXLNA | c.340C>A p.R114= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, varscan2
- HLA-L | n.1032C>A | RNA (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- KANSL2 | c.-10+256C>G | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as rs564347079; called by muse, mutect2, varscan2
- MEIS3P1 | n.500G>A | RNA (SNP) | VAF 7/32 reads (22%) | called by muse, varscan2
- STAR | c.745-16C>G | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
